Somatic mutation profile of tumor specimen MP2PRT-PAUPZW-TMP1-A (aliquot MP2PRT-PAUPZW-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUPZW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,100 days).
Specimen MP2PRT-PAUPZW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea65a97a-be37-4498-8696-05c7e57fad56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPZW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPZW-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16e8d264-192a-46d4-b645-5f2af713ad75

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 8, Nonsense Mutation 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.8059C>T p.R2687* | Nonsense Mutation (SNP) | VAF 51/366 reads (14%) | catalogued as rs1555191598, CM122093, COSV56441698; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); catalogued as rs577173358, COSV59750303; called by muse, mutect2, varscan2
- CALML5 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 26/712 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV66702592; called by muse, mutect2
- MROH5 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 82/789 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as rs754886605; called by muse, mutect2, varscan2
- MYRIP | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 73/424 reads (17%) | catalogued as rs1246568283; called by muse, mutect2, varscan2
- NINL | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 40/642 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1385556490; called by muse, mutect2
- A1CF | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 40/530 reads (8%) | called by muse, mutect2
- ADAM19 | c.1908T>C p.H636= | Splice Region (SNP) | VAF 86/261 reads (33%) | called by muse, mutect2, varscan2
- CDADC1 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ELP1 | c.3437A>C p.E1146A | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOXA1 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 43/457 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TPGS2 | c.48C>A p.H16Q | Missense Mutation (SNP) | VAF 153/916 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- AK9 | c.3420A>G p.G1140= | Silent (SNP) | VAF 31/288 reads (11%) | called by muse, mutect2, varscan2
- BECN2 | c.129G>A p.R43= | Silent (SNP) | VAF 38/726 reads (5%) | called by muse, mutect2
- C19orf85 | c.36C>T p.S12= | Silent (SNP) | VAF 73/689 reads (11%) | catalogued as rs1161982941; called by muse, mutect2, varscan2
- JADE2 | c.939C>T p.L313= | Silent (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- LEXM | c.57G>A p.T19= | Silent (SNP) | VAF 85/609 reads (14%) | called by muse, mutect2, varscan2
- LZTS1 | c.123G>T p.L41= | Silent (SNP) | VAF 50/497 reads (10%) | called by muse, mutect2, varscan2
- PCDH8 | c.2124C>T p.F708= | Silent (SNP) | VAF 218/578 reads (38%) | catalogued as COSV58812924; called by muse, mutect2, varscan2
- SLC27A5 | c.906G>A p.P302= | Silent (SNP) | VAF 52/253 reads (21%) | catalogued as rs757298753, COSV54018095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDLIM5 | c.96+45T>G | Intron (SNP) | VAF 70/529 reads (13%) | called by muse, mutect2, varscan2
